Somatic mutation profile of tumor specimen MMRF_2514_1_BM_CD138pos (aliquot MMRF_2514_1_BM_CD138pos_T1_KHS5U_K15147) from MMRF case MMRF_2514, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,138 days).
Specimen MMRF_2514_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 033f318e-2357-4cf2-9f94-8ae1f2e2c383.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2514_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2514_1_PB_Whole_C3_KHS5U_K15146; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50e7091b-e512-4d59-bbf0-acea8e9a610b

The open-access MAF lists 165 somatic variants for this specimen: 73 protein-altering or splice-affecting, 22 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, 3'UTR 40, Silent 22, Intron 18, 5'UTR 6, Nonsense Mutation 5, 3'Flank 3, Splice Region 3, RNA 2, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 13/162 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 27/154 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOX3 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749601229, COSV100712070; called by muse, mutect2, varscan2
- ANHX | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs866559228; called by muse, mutect2, varscan2
- ATG16L2 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs139269726; called by muse, mutect2, varscan2
- DYM | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV53991370; called by muse, mutect2, varscan2
- GABRQ | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 86/96 reads (90%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV64783950; called by muse, mutect2, varscan2
- GNPTAB | c.53A>C p.Y18S | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV67373727; called by muse, mutect2, varscan2
- IGHV1-69 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs184214708; called by muse, mutect2
- IGHV1-69D | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGHV2-70 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs373048671; called by muse, varscan2
- IGHV2-70D | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1414572352; called by muse, varscan2
- KRT71 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1475470437; called by muse, mutect2, varscan2
- LRP1B | c.5903A>T p.Y1968F | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV67261071; called by muse, mutect2, varscan2
- MED13L | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867033906, COSV56116816; called by mutect2, varscan2
- MLF1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 27/178 reads (15%) | catalogued as rs1438356147, COSV63035223; called by muse, mutect2, varscan2
- MOK | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 71/141 reads (50%) | catalogued as rs141604419, COSV99513345; called by muse, mutect2, varscan2
- MTUS1 | c.2720A>G p.Q907R (on ENST00000262102 / NM_001363061.1; = p.Q73R on NM_020749.4) | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1362454566, COSV99870692; called by muse, mutect2
- NMNAT1 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as rs866227307; called by muse, mutect2, varscan2
- OTOG | c.5057A>C p.K1686T | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100696068; called by muse, mutect2, varscan2
- PCDHB5 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.975); catalogued as rs782121687, COSV50673381; called by muse, mutect2, varscan2
- PLXNA4 | c.3178G>A p.V1060I | Missense Mutation (SNP) | VAF 114/204 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs200738128, COSV104414484; called by muse, mutect2
- POU4F3 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 96/412 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV57942353; called by muse, mutect2, varscan2
- PPP2R5D | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 179/292 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as COSV55151009; called by muse, mutect2, varscan2
- PTH2R | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs759008399; called by muse, mutect2, varscan2
- RPGR | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM971311; called by muse, mutect2, varscan2
- SAGE1 | c.2318A>T p.D773V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV61015387; called by muse, mutect2
- SLC24A4 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as rs777737747, COSV54109555; called by muse, mutect2, varscan2
- SRRM3 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as rs374404680, COSV100418640; called by muse, mutect2, varscan2
- TBC1D4 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 104/129 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs201208079; called by muse, mutect2, varscan2
- TCHH | c.5438G>A p.R1813H | Missense Mutation (SNP) | VAF 112/361 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs570255654; called by muse, mutect2, varscan2
- VTN | c.496del p.D166Tfs*23 | Frame Shift Del (DEL) | VAF 54/154 reads (35%) | catalogued as COSV99879602; called by mutect2, pindel, varscan2
- ARAP3 | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- ATP8B2 | c.712A>G p.N238D (on ENST00000672630; = p.N205D on NM_001005855.2) | Missense Mutation (SNP) | VAF 12/418 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BHLHE41 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CACNB1 | c.414G>A p.E138= | Splice Region (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- CACNG5 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CORO2B | c.765+1G>T p.X255_splice | Splice Site (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- CTNNA2 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EYA4 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 22/227 reads (10%) | called by muse, mutect2
- FGFR2 | c.1515A>C p.K505N | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- FMN2 | c.4301C>T p.P1434L | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALC | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- IGHV2-70D | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, varscan2
- IGHV2-70D | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, varscan2
- IGLV5-45 | c.121T>G p.C41G | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, varscan2
- IGLV5-45 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, varscan2
- JPH4 | c.1544_1555del p.E515_A518del | In Frame Del (DEL) | VAF 53/184 reads (29%) | called by mutect2, varscan2
- LGSN | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MORC3 | c.2639A>C p.E880A | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO16 | c.5259T>C p.G1753= | Splice Region (SNP) | VAF 15/96 reads (16%) | called by mutect2, varscan2
- NDRG3 | c.923A>T p.Y308F (on ENST00000349004 / NM_032013.4; = p.Y296F on NM_022477.4) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NETO2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLIG3 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2
- OR5H6 | c.700T>C p.Y234H (on ENST00000642105; = p.Y218H on NM_001005479.2) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8B8 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- PARVG | c.145-7C>A | Splice Region (SNP) | VAF 71/171 reads (42%) | called by muse, mutect2, varscan2
- PDXDC1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLXNC1 | c.4070C>G p.T1357S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- PM20D1 | c.1470C>G p.D490E | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PSD3 | c.1903T>C p.S635P | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RGS6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 101/244 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ROBO1 | c.1706T>A p.V569E | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO4 | c.2719G>T p.A907S | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- SOX14 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 15/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SOX30 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- TBC1D32 | c.1278T>A p.Y426* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- TTLL11 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TTN | c.87064A>T p.S29022C (on ENST00000591111; = p.S21598C on NM_003319.4) | Missense Mutation (SNP) | VAF 84/160 reads (53%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBBX | c.94_95insG p.K32Rfs*7 | Frame Shift Ins (INS) | VAF 31/261 reads (12%) | called by mutect2, pindel, varscan2
- ZC3H3 | c.2204G>A p.G735D | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF484 | c.1456C>A p.H486N | Missense Mutation (SNP) | VAF 34/451 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF671 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM17 | c.267T>C p.R89= | Silent (SNP) | VAF 118/258 reads (46%) | catalogued as rs770087502; ClinVar: likely benign; called by muse, varscan2
- ADGRF2 | c.2010C>T p.V670= (on ENST00000296862 / NM_001368115.2; = p.V602= on NM_153839.7) | Silent (SNP) | VAF 28/378 reads (7%) | called by muse, mutect2
- AVPI1 | c.312G>A p.L104= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV65697294; called by muse, mutect2, varscan2
- CCDC105 | c.426C>T p.R142= | Silent (SNP) | VAF 46/73 reads (63%) | called by muse, mutect2, varscan2
- DMRTA2 | c.678C>T p.P226= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs1357624895; called by muse, mutect2
- EGR1 | c.99T>A p.P33= | Silent (SNP) | VAF 218/500 reads (44%) | catalogued as rs759975233; called by muse, mutect2, varscan2
- EI24 | c.807C>G p.L269= | Silent (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- ELAVL2 | c.30T>G p.T10= | Silent (SNP) | VAF 42/734 reads (6%) | catalogued as COSV99807555; called by muse, mutect2
- ERMARD | c.1194A>T p.L398= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- FAM135B | c.306C>T p.D102= | Silent (SNP) | VAF 71/166 reads (43%) | catalogued as rs752363670; called by muse, mutect2, varscan2
- H1-4 | c.288C>G p.T96= | Silent (SNP) | VAF 58/162 reads (36%) | catalogued as rs376979971; called by muse, mutect2, varscan2
- IGHE | c.588C>G p.T196= | Silent (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- IGLV5-45 | c.183A>G p.P61= | Silent (SNP) | VAF 64/168 reads (38%) | called by muse, varscan2
- INPP5D | c.1284C>T p.S428= (on ENST00000445964 / NM_001017915.3; = p.S427= on NM_005541.5) | Silent (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- LRTM1 | c.984C>T p.T328= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as COSV55559553; called by muse, mutect2
- OR2K2 | c.216C>T p.S72= (on ENST00000374428; = p.S43= on NM_205859.2) | Silent (SNP) | VAF 252/536 reads (47%) | catalogued as rs1056315811; called by muse, mutect2, varscan2
- PIWIL2 | c.2478C>T p.A826= | Silent (SNP) | VAF 74/152 reads (49%) | catalogued as rs376173992; called by muse, mutect2, varscan2
- PLPPR3 | c.1761G>C p.A587= (on ENST00000520876 / NM_001270366.2; = p.A615= on NM_024888.2) | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as COSV100608299; called by muse, mutect2
- TACC2 | c.8787A>G p.K2929= (on ENST00000334433; = p.K1007= on NM_006997.4) | Silent (SNP) | VAF 106/255 reads (42%) | called by muse, mutect2, varscan2
- TTBK1 | c.27G>A p.K9= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as rs751441680, COSV52497963; called by muse, mutect2
- ZNF675 | c.27G>A p.V9= | Silent (SNP) | VAF 111/346 reads (32%) | called by muse, mutect2, varscan2
- ZZEF1 | c.5082C>A p.L1694= | Silent (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- ARID1B | c.4986+169A>T | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- ATP6V1D | c.*146T>C | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- BCKDK | c.643-46G>A | Intron (SNP) | VAF 9/56 reads (16%) | catalogued as rs1212489705; called by muse, mutect2, varscan2
- BMP2KL | n.536T>G | RNA (SNP) | VAF 39/50 reads (78%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+2402G>T | Intron (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- CHMP2B | c.*207A>T | 3'UTR (SNP) | VAF 36/74 reads (49%) | called by muse, varscan2
- CHMP2B | c.*271A>G | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, varscan2
- DCSTAMP | c.*432G>T | 3'UTR (SNP) | VAF 69/161 reads (43%) | called by muse, mutect2, varscan2
- DENND5A | c.*678G>T | 3'UTR (SNP) | VAF 5/33 reads (15%) | catalogued as rs970677077, COSV60234158; called by muse, mutect2, varscan2
- DOCK5 | c.5405-145T>A | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- DTX1 | c.*1023C>T | 3'UTR (SNP) | VAF 57/116 reads (49%) | catalogued as rs1416320877; called by muse, mutect2, varscan2
- ELAVL3 | c.*2C>T | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- EYS | c.1766+2936A>C | Intron (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- FAM89A | c.292-5900G>A | Intron (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- G2E3 | c.*1571A>C | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- GJC1 | c.*7C>T | 3'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as rs573630531, COSV57912829; called by muse, mutect2
- GMNC | c.*950G>T | 3'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- GNAO1 | c.-74G>A | 5'UTR (SNP) | VAF 30/60 reads (50%) | catalogued as rs1034791551; called by muse, mutect2, varscan2
- GNAS | c.2068+1045A>T | Intron (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- GPLD1 | c.*594G>A | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2
- HEY1 | c.-23C>A | 5'UTR (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- HNRNPU | chr1:244852948 G>A | 3'Flank (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- HS3ST3B1 | c.-84C>T | 5'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs1023380876; called by muse, mutect2, varscan2
- ID1 | c.*311A>C | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- IL1R1 | c.*2427C>A | 3'UTR (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- KDM5A | c.*2433G>A | 3'UTR (SNP) | VAF 9/84 reads (11%) | catalogued as rs1031223874; called by muse, mutect2, varscan2
- KLHL9 | c.*470T>C | 3'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- LTB | c.209-23C>G | Intron (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- LTB | c.163-166C>T | Intron (SNP) | VAF 64/219 reads (29%) | catalogued as COSV53002630; called by muse, mutect2, varscan2
- LTB | c.162+138T>C | Intron (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- LY6K | c.217+387C>T | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs908537573; called by muse, mutect2
- MGAM | c.4618+3216G>A | Intron (SNP) | VAF 19/61 reads (31%) | catalogued as rs756917594, COSV101527705; called by muse, mutect2
- MRPL4 | c.739+22C>T | Intron (SNP) | VAF 99/158 reads (63%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-1303C>T | Intron (SNP) | VAF 66/813 reads (8%) | catalogued as rs756327232; called by muse, mutect2
- NFATC3 | c.*2239C>T | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- NNMT | c.*557A>T | 3'UTR (SNP) | VAF 24/68 reads (35%) | catalogued as rs1003467772; called by muse, mutect2, varscan2
- OTULIN | c.*6638A>G | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- PDGFC | c.*1313C>G | 3'UTR (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- PEG3 | c.*3369T>C | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- PET117 | c.*625T>G | 3'UTR (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- PHKA2 | c.*277G>A | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- PIGR | c.*1590C>T | 3'UTR (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- PIK3CD | c.1471-24G>A | Intron (SNP) | VAF 21/48 reads (44%) | catalogued as rs369629182; called by muse, mutect2, varscan2
- PKIA | chr8:78604638 G>A | 3'Flank (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- POU4F2 | c.-126C>T | 5'UTR (SNP) | VAF 8/123 reads (7%) | catalogued as COSV55583576; called by muse, mutect2
- PRDM16 | chr1:3067671 C>T | 5'Flank (SNP) | VAF 8/18 reads (44%) | catalogued as rs1354322415; called by muse, mutect2
- PRDM6 | c.*696C>T | 3'UTR (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- PREX2 | c.*324G>A | 3'UTR (SNP) | VAF 28/54 reads (52%) | catalogued as rs981994026; called by muse, mutect2, varscan2
- PRR16 | c.*18del | 3'UTR (DEL) | VAF 224/543 reads (41%) | catalogued as rs771728312; called by mutect2, pindel, varscan2
- PTGR2 | c.*439C>A | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- PVR | c.*1350G>A | 3'UTR (SNP) | VAF 23/51 reads (45%) | catalogued as rs1415863561; called by muse, mutect2, varscan2
- RHOU | c.*2788C>T | 3'UTR (SNP) | VAF 15/79 reads (19%) | catalogued as rs1291120524; called by muse, mutect2, varscan2
- RIMKLB | c.*3085C>T | 3'UTR (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- RNF217 | c.*7756A>G | 3'UTR (SNP) | VAF 33/107 reads (31%) | catalogued as rs899224326; called by muse, mutect2, varscan2
- RNFT2 | c.*3952G>A | 3'UTR (SNP) | VAF 35/88 reads (40%) | catalogued as rs750621237; called by muse, mutect2, varscan2
- ROBO1 | c.3374-495A>C | Intron (SNP) | VAF 44/109 reads (40%) | called by muse, mutect2, varscan2
- RPSA | c.793+12G>A | Intron (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- SFXN1 | c.*833C>T | 3'UTR (SNP) | VAF 7/190 reads (4%) | called by muse, mutect2
- SHROOM3 | c.*562C>T | 3'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs756261277; called by muse, mutect2, varscan2
- SI | c.*240A>T | 3'UTR (SNP) | VAF 52/94 reads (55%) | called by muse, mutect2, varscan2
- SLX4IP | c.406-7817T>G | Intron (SNP) | VAF 42/247 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-18 | chr15:25090112 G>C | 3'Flank (SNP) | VAF 45/168 reads (27%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1558G>A | RNA (SNP) | VAF 20/36 reads (56%) | catalogued as rs1190279645; called by muse, mutect2, varscan2
- TASP1 | c.-69T>G | 5'UTR (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- TMPO | c.*1362T>G | 3'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- TNFRSF18 | c.*178G>A | 3'UTR (SNP) | VAF 40/89 reads (45%) | catalogued as rs1260835390; called by muse, mutect2, varscan2
- TPRG1 | c.*3424G>A | 3'UTR (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- WRNIP1 | c.*1091G>C | 3'UTR (SNP) | VAF 15/222 reads (7%) | called by muse, mutect2
- ZIC3 | c.-327dup | 5'UTR (INS) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- ZXDB | c.*2659T>A | 3'UTR (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
